Gene-level copy-number profile of tumor specimen TCGA-UL-AAZ6-01A from TCGA case TCGA-UL-AAZ6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.9 years (26,999 days).
Specimen TCGA-UL-AAZ6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.d1990a4b-9db1-4f6f-9564-eed89ccc47f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UL-AAZ6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96403613-def0-4359-8829-dbbcc5b7bc83

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 731; copy number 2: 12,552; copy number 3: 21,503; copy number 4: 18,020; copy number 5: 3,997; copy number 6: 1,543; copy number 7: 503; copy number 8: 347; copy number 9: 35; copy number 10: 160; copy number 11: 79; copy number 12: 51; copy number 13: 7; copy number 14: 15; copy number 15: 27; copy number 17: 66; copy number 25: 63; copy number 26: 5; copy number 35: 7; copy number 36: 59; copy number 41: 31; copy number 57: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UL-AAZ6-01A-11D-A41E-01): tumor purity 0.91, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,464 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,938,104–42,035,925, 20 genes, copy number 8 (within-gene range 6–8): AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17, AC093151.7, AC093151.2, AC093151.1, AC093151.5, FOXO6, FOXO6-AS1, RNA5SP45, EDN2, HIVEP3, AL445933.2, AL445933.1, AC119676.1.
- chr1:214,603,195–214,664,571, 3 genes, copy number 7 (within-gene range 6–7): CENPF, ABHD17AP3, UBE2V1P13.
- chr4:68,704,600–69,250,815, 29 genes, copy number 7: AC147055.1, AC093720.1, AC021146.8, UGT2B10, AC021146.9, AC021146.4, AC021146.11, AC021146.2, AC021146.3, AC021146.12, AC021146.6, AC021146.1, UGT2A3, AC021146.10, AC021146.5, AC021146.7, UGT2B27P, AC107401.1, UGT2B26P, UGT2B7, AC111000.2, AC111000.5, AC111000.3, AC111000.6, AC111000.1, AC111000.4, UGT2B11, AC114797.1, AC114786.1.
- chr4:154,583,128–154,828,813, 10 genes, copy number 7 (within-gene range 4–7): FGA, FGG, AC107385.2, LRAT, NDUFB2P1, AC009567.1, AC009567.2, RBM46, RNU2-66P, RNU2-44P.
- chr4:161,383,897–164,384,050, 20 genes, copy number 7 (within-gene range 2–7): FSTL5, AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12, TKTL2, TMA16, MARCHF1, AC093788.1, RN7SKP105, YWHAQP4.
- chr5:50,396,192–51,665,048, 21 genes, copy number 9 (within-gene range 6–9): EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr7:86,643,914–87,399,794, 14 genes, copy number 7: GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT.
- chr8:116,022,686–116,022,779, 1 gene, copy number 7: RNA5SP276.
- chr11:68,754,620–70,207,390, 43 genes, copy number 7: CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr13:20,777,329–22,276,526, 37 genes, copy number 8 (within-gene range 2–8): XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54, LATS2, LATS2-AS1, RNU4-9P, RPS12P23, IPPKP1, AL161613.1, SNORD27, SAP18, SKA3, MRPL57, AL158032.1, LINC01046, ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1, GAPDHP52, RNA5SP25, ZDHHC20, ZDHHC20-IT1, H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9, RN7SL766P, LINC00424, LINC00540, NME1P1, MTND3P1.
- chr13:34,942,287–35,673,022, 1 gene, copy number 8 (within-gene range 2–8): NBEA.
- chr13:35,251,070–36,131,382, 5 genes, copy number 8 (within-gene range 4–8): PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1.
- chr14:30,819,714–32,837,684, 43 genes, copy number 7 (within-gene range 4–7): AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2.
- chr14:51,826,195–52,328,598, 12 genes, copy number 8 (within-gene range 4–8): GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2, LINC02319, COX5AP2, AL118557.1, PTGDR, AL365475.1, PTGER2.
- chr15:19,878,555–26,053,123, 293 genes, copy number 8–26 (broad region; genes not listed).
- chr15:44,665,732–47,774,228, 76 genes, copy number 7–15 (within-gene range 4–15) (broad region; genes not listed).
- chr15:47,812,729–52,938,518, 130 genes, copy number 7–25 (within-gene range 4–25) (broad region; genes not listed).
- chr17:30,115,521–30,186,475, 1 gene, copy number 8 (within-gene range 6–8): NSRP1.
- chr17:30,144,062–30,831,318, 36 genes, copy number 8 (within-gene range 6–8): AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1.
- chr17:37,375,985–37,884,743, 15 genes, copy number 14 (within-gene range 2–14): C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7.
- chr17:39,200,283–40,195,656, 43 genes, copy number 36: RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867.
- chr17:56,978,129–62,841,645, 194 genes, copy number 10–57 (broad region; genes not listed).
- chr17:63,009,556–63,427,699, 7 genes, copy number 35 (within-gene range 2–35): TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7.
- chr19:29,698,886–35,581,954, 174 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr19:36,259,540–36,913,029, 26 genes, copy number 10 (within-gene range 2–10): LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA.
- chr19:39,726,030–40,380,439, 30 genes, copy number 7 (within-gene range 4–7): AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796.
- chr19:47,403,124–47,581,321, 9 genes, copy number 8: MEIS3, SLC8A2, AC073548.2, KPTN, NAPA-AS1, NAPA, AC073548.1, ZNF541, RN7SL322P.
- chr19:49,157,741–49,640,143, 37 genes, copy number 7 (within-gene range 1–7): TRPM4, SLC6A21P, SUMO1P4, SLC6A16, MIR4324, AC011450.1, CD37, TEAD2, AC010524.1, DKKL1, AC010643.1, KASH5, PTH2, GFY, SLC17A7, PIH1D1, ALDH16A1, AC010619.1, FLT3LG, AC010619.2, RPL13A, SNORD32A, SNORD33, SNORD34, SNORD35A, RPS11, SNORD35B, MIR150, COX6CP7, FCGRT, RCN3, NOSIP, Y_RNA, PRRG2, PRR12, AC011495.2, RRAS.
- chr19:56,567,468–56,922,213, 14 genes, copy number 9: ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835, AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1.
- chr20:52,840,936–52,890,386, 3 genes, copy number 7: AL161945.1, AL121902.1, RPL36P1.
- chr20:53,552,770–54,859,812, 16 genes, copy number 8–11: AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.
- chr20:55,607,852–59,325,992, 92 genes, copy number 8–11 (within-gene range 6–11) (broad region; genes not listed).
- chr20:61,252,261–61,940,617, 1 gene, copy number 10 (within-gene range 6–10): CDH4.
- chr20:61,717,506–62,135,374, 8 genes, copy number 10 (within-gene range 5–10): AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B.

Autosomal genes at a single copy (total copy number 1): 731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
